Somatic mutation profile of tumor specimen TCGA-VR-A8EY-01A (aliquot TCGA-VR-A8EY-01A-11D-A36J-09) from TCGA case TCGA-VR-A8EY, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 44.5 years (16,255 days).
Specimen TCGA-VR-A8EY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 085f895f-534d-4700-aa44-98171d4f3ae3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EY-10A (Blood Derived Normal), aliquot TCGA-VR-A8EY-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c9980fc-4e06-40e5-bbe9-c6d6d1c306d6

The open-access MAF lists 105 somatic variants for this specimen: 84 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 20, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 3, Splice Region 2, Nonstop Mutation 1, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM29 | c.325del p.D109Tfs*21 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as COSV63659808; called by pindel, varscan2
- ADGRA1 | c.989C>A p.T330N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs897809324; called by muse, mutect2, varscan2
- ADGRA1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776693044, COSV66924677; called by muse, mutect2, varscan2
- ANKRD24 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as rs778596061; called by muse, mutect2, varscan2
- ARID5A | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs150071690; called by muse, mutect2, varscan2
- ASAH2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549196716, COSV61483335; called by muse, mutect2, varscan2
- C3 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs753544234; called by muse, mutect2, varscan2
- CDH6 | c.1075C>G p.L359V | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV99421238; called by muse, mutect2
- CNTN3 | c.3079C>A p.L1027M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs1211504095; called by muse, mutect2, varscan2
- CNTNAP5 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV101442982; called by muse, mutect2
- COL15A1 | c.723G>A p.S241= | Splice Region (SNP) | VAF 64/80 reads (80%) | catalogued as rs199838728; called by muse, mutect2, varscan2
- CROCC | c.3290G>C p.R1097P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs6669627, COSV65013770; called by muse, mutect2
- CSMD3 | c.6086T>G p.F2029C (on ENST00000297405 / NM_001363185.1; = p.F1925C on NM_052900.3) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104398036; called by muse, mutect2, varscan2
- EPHA7 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776802108, COSV65181235; called by muse, mutect2, varscan2
- FBN2 | c.7558G>A p.G2520R | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52514672; called by muse, mutect2, varscan2
- FRG2C | c.695C>A p.A232E | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs1385213879; called by muse, mutect2, varscan2
- FRMPD2 | c.2180G>T p.R727L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100564058; called by muse, mutect2, varscan2
- G2E3 | c.1972G>T p.V658L | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs1475279156; called by muse, mutect2, varscan2
- LEFTY2 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs202147285; called by muse, mutect2, varscan2
- LILRA1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.88); PolyPhen benign (0.009); catalogued as rs368541946; called by muse, mutect2, varscan2
- LRCH1 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.354); catalogued as rs897275239; called by muse, mutect2, varscan2
- MAMLD1 | c.1404G>T p.L468F | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs1557406441; called by muse, mutect2
- MORC4 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV55239114; called by muse, mutect2, varscan2
- MROH9 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV63012540; called by muse, mutect2, varscan2
- MYH2 | c.4435G>T p.E1479* | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as COSV55438090; called by muse, mutect2, varscan2
- NDST2 | c.1246C>G p.L416V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs534521520; called by muse, mutect2, varscan2
- NKAP | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs768575536, COSV65056820; called by muse, mutect2, varscan2
- NOTCH1 | c.1099+1G>A p.X367_splice | Splice Site (SNP) | VAF 98/118 reads (83%) | catalogued as COSV53081278; called by muse, mutect2, varscan2
- PCSK6 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs759298704, COSV100083347; called by muse, mutect2, varscan2
- PGS1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752050948, COSV99428300; called by muse, mutect2, varscan2
- PHEX | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65075650; called by muse, mutect2, varscan2
- PLD5 | c.1249G>C p.D417H (on ENST00000442594; = p.D355H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.855); catalogued as COSV59152604; called by muse, mutect2, varscan2
- PTPRD | c.1518C>A p.D506E | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.417); catalogued as COSV61970845; called by muse, mutect2, varscan2
- SALL4 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs747787961, COSV53850364; called by muse, mutect2, varscan2
- SEMA3F | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1177203082; called by muse, mutect2, varscan2
- SIX6 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1446659494, COSV100576576; called by muse, mutect2, varscan2
- TP53 | c.124del p.D42Ifs*2 | Frame Shift Del (DEL) | VAF 54/85 reads (64%) | catalogued as COSV53625330; called by mutect2, pindel, varscan2
- UFSP2 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52992708; called by muse, mutect2, varscan2
- USP25 | c.1048C>G p.H350D | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as COSV53488746; called by muse, mutect2, varscan2
- ZEB2 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57953031; called by muse, mutect2, varscan2
- ZFP37 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.556); catalogued as COSV100953101; called by muse, mutect2, varscan2
- ZNF707 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs782359327, COSV62311017; called by muse, mutect2, varscan2
- ABHD16A | c.344-2A>C p.X115_splice | Splice Site (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.4125+1G>A p.X1375_splice | Splice Site (SNP) | VAF 148/235 reads (63%) | called by muse, mutect2, varscan2
- ADD2 | c.951G>A p.V317= | Splice Region (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- ALOX15B | c.56G>C p.W19S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- APOB | c.10768G>C p.E3590Q | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BCL2A1 | c.272C>G p.T91S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCL25 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- CDK11A | c.1615A>G p.K539E (on ENST00000378633 / NM_001313896.2; = p.K536E on NM_024011.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.334); called by muse, mutect2
- CUX2 | c.3728G>A p.G1243D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ENTPD1 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- FCRL2 | c.26T>C p.I9T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- FRMD8 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDPD4 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 98/161 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA3 | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- GPR139 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ICE1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- INTS10 | c.376T>A p.L126I | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- MCF2L2 | c.2063T>C p.L688S | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH10 | c.3215C>A p.A1072E | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.197); called by muse, mutect2
- NCAPG2 | c.2392G>T p.D798Y | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- NLRP12 | c.1932G>T p.K644N | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- NPVF | c.174T>G p.N58K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- NTRK1 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NUDT12 | c.195del p.E67Rfs*28 | Frame Shift Del (DEL) | VAF 45/121 reads (37%) | called by mutect2, pindel, varscan2
- OR2M3 | c.938G>C p.*313Sext*3 | Nonstop Mutation (SNP) | VAF 56/114 reads (49%) | called by muse, mutect2, varscan2
- OR5M11 | c.650_655del p.Y217_A218del | In Frame Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- PACS1 | c.2785G>A p.D929N | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAPOLB | c.1840G>C p.V614L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.011); called by muse, mutect2
- PCLO | c.12794G>C p.G4265A | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PCLO | c.5089C>G p.P1697A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SALL2 | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SI | c.4993A>G p.I1665V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SNTA1 | c.410_413del p.S137* | Frame Shift Del (DEL) | VAF 49/68 reads (72%) | called by pindel, varscan2
- SYNE1 | c.21513C>G p.D7171E (on ENST00000367255 / NM_182961.4; = p.D7100E on NM_033071.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNPO1 | c.2689G>T p.G897C | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TOMM40 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TRIM27 | c.830T>G p.I277S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TWNK | c.2016dup p.T673Hfs*23 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- USP32 | c.3269T>A p.F1090Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ZC3H12B | c.1283A>G p.K428R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF430 | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- ZNF789 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- ADGRV1 | c.1293G>A p.A431= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs773901506, COSV67977462; called by muse, mutect2, varscan2
- C9orf24 | c.510G>A p.S170= | Silent (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- CA8 | c.651G>T p.V217= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- CASC3 | c.1857T>C p.P619= | Silent (SNP) | VAF 59/90 reads (66%) | called by muse, mutect2, varscan2
- CECR2 | c.450C>T p.D150= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs1197109880; called by muse, mutect2, varscan2
- COL5A1 | c.2115G>A p.P705= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs1255184161; called by muse, mutect2
- DNAH9 | c.6201C>T p.D2067= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- GGCT | c.279T>G p.S93= | Silent (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- KCNJ12 | c.438C>T p.Y146= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs782723700, COSV59163395; called by muse, mutect2, varscan2
- LMF1 | c.1209C>T p.V403= | Silent (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- MAGEC1 | c.624C>G p.S208= | Silent (SNP) | VAF 68/392 reads (17%) | called by muse, varscan2
- MYH1 | c.4275C>G p.L1425= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- MYO16 | c.4563C>T p.V1521= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- NPAS4 | c.453C>T p.F151= | Silent (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- OR2A7 | c.147A>T p.S49= | Silent (SNP) | VAF 34/348 reads (10%) | called by muse, mutect2
- SLC17A6 | c.312C>T p.I104= | Silent (SNP) | VAF 58/160 reads (36%) | catalogued as COSV54133930; called by muse, mutect2, varscan2
- SPTLC1 | c.369A>G p.A123= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- UBN1 | c.3234C>G p.A1078= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- USP37 | c.1800A>G p.P600= | Silent (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- WDR49 | c.420C>A p.A140= (on ENST00000308378 / NM_001366158.1; = p.A481= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- NXF5 | n.894T>C | RNA (SNP) | VAF 101/267 reads (38%) | called by muse, mutect2, varscan2
